Somatic mutation profile of tumor specimen C3L-06361-54 (aliquot CPT0345610002) from CPTAC case C3L-06361, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 68.9 years (25,154 days).
Specimen C3L-06361-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8f8cf78-d7a3-4b2c-8479-a437ec97c4a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06361-50 (Buccal Cell Normal), aliquot CPT0345580003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7bb94b48-eff8-4d3e-9ce6-63c6fe386cf8

The open-access MAF lists 2 somatic variants for this specimen: 2 silent.
By variant classification: Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PARD6G | c.330G>A p.S110= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV62062438; called by muse, mutect2, varscan2
- TCF7L1 | c.135G>A p.G45= | Silent (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2, varscan2
